Surgical pathology report (de-identified scan), TCGA case TCGA-AG-3582, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AG-3582-01A (Primary Tumor).

Diagnosis/diagnoses:

Resected colon shows a moderately differentiated, ulcerated adenocarcinoma of the colorectal type, measuring a max of 5 cm, with infiltration of the pericolic fatty tissue. Circumscribed – tuberous, peritoneal tumor metastasis located distally to the tumor. In addition, tumor-free regional lymph nodes. Tumor-free mesenteric resection margin. Tumor-free colon resection margins.

The tuberous, peritoneal tumor metastasis must first and foremost be assessed in relation to a lymph node metastasis.

Stage of tumor: pT3, pN1 (1/28) pM1; G2, L0, V0, R2.

Source: NCI Genomic Data Commons file 81324053-93d1-4ff9-aca4-76c5e1a9edcb (TCGA-AG-3582.8224F921-88C4-48D2-BAF8-6E81DB94661B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).